Gene-level copy-number profile of tumor specimen ALCH-ADU3-TTP1-A from ALCHEMIST case ALCH-ADU3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 54.2 years (19,804 days).
Specimen ALCH-ADU3-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 670a289b-5262-43d3-8421-d7a944d25545.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADU3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/534b8662-7e0b-40c0-b318-bf37ed50c262

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 569; copy number 1: 12,249; copy number 2: 41,259; copy number 3: 3,659; copy number 4: 927; copy number 5: 223.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 11 genes (within-gene range 0–3): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr14:105,467,793–105,537,239, 7 genes (within-gene range 0–1): AL928654.2, CRIP2, CRIP1, AL928654.3, TEDC1, TMEM121, ATP5MC1P1.
- chr15:43,614,208–43,684,339, 6 genes: AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2, AC011330.1.
- chr15:74,445,977–74,831,795, 16 genes (within-gene range 0–2): UBL7, UBL7-AS1, AC012435.2, AC012435.3, AC012435.1, ARID3B, CLK3, AC100835.2, AC100835.1, EDC3, CYP1A1, CYP1A2, CSK, MIR4513, LMAN1L, AC091230.1.
- chr18:49,116,301–49,126,479, 1 gene (within-gene range 0–1): AC016866.2.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:29,194,071–29,630,751, 1 gene (within-gene range 0–1): BACH1.
- chr21:29,351,634–29,500,386, 5 genes: BACH1-IT1, AP000240.1, BACH1-AS1, BACH1-IT2, BACH1-IT3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 223 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:188,153,284–188,890,671, 1 gene, copy number 5 (within-gene range 4–5): LPP.
- chr3:188,562,238–198,123,232, 211 genes, copy number 5 (broad region; genes not listed).
- chr9:34,810,020–35,011,285, 11 genes, copy number 5: AL589645.1, FAM205BP, FAM205C, GLULP4, YWHAZP6, PHF24, DNAJB5-DT, DNAJB5, AL355377.1, AL355377.2, SYF2P2.

Autosomal genes at a single copy (total copy number 1): 9,913. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
